CCDI case PBBTNY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/659edc18-81dd-4e20-b956-39c65f6aa112

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.5 years (898 days).

Biospecimens (3 samples)
- Sample 0DGMHF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGMHO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DGMI1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
